Somatic mutation profile of tumor specimen TCGA-OR-A5KB-01A (aliquot TCGA-OR-A5KB-01A-11D-A30A-10) from TCGA case TCGA-OR-A5KB, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.7 years (22,550 days).
Specimen TCGA-OR-A5KB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d91a0e4-8ce6-431a-afbe-c988048ab1aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KB-11A (Solid Tissue Normal), aliquot TCGA-OR-A5KB-11A-11D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71cf7f4c-5b56-4425-b797-82bc9419a5d7

The open-access MAF lists 2,205 somatic variants for this specimen: 1,656 protein-altering or splice-affecting, 495 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,418, Silent 495, Nonsense Mutation 119, Splice Site 44, Frame Shift Del 38, Intron 22, Splice Region 21, RNA 16, Frame Shift Ins 11, 5'UTR 6, 3'UTR 6, In Frame Del 3.

Variants (750 of 2,205; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ3 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1085307996; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 97/165 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58822445, COSV58825728, COSV58829155; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 64/156 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 18/85 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, varscan2
- USH2A | c.949C>A p.R317= | Silent (SNP) | VAF 71/161 reads (44%) | catalogued as rs111033272, CS042173; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs533605370, COSV54050119; called by muse, mutect2, varscan2
- ABCA6 | c.3112G>T p.D1038Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52634938; called by muse, mutect2, varscan2
- ABCC11 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764029698; called by muse, mutect2, varscan2
- AC098582.1 | c.2528A>C p.E843A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs910369229; called by muse, mutect2, varscan2
- AC136428.1 | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99067802; called by muse, mutect2, varscan2
- AC231657.3 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs782710721; called by muse, mutect2, varscan2
- ACSM2A | c.274C>T p.Q92* (on ENST00000219054; = p.Q13* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 52/385 reads (14%) | catalogued as rs1374735615, COSV54582527, COSV54584050; called by muse, mutect2, varscan2
- ACTBL2 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV101379381; called by muse, varscan2
- ACTN2 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV104426780; called by muse, varscan2
- ADAM12 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV64116295; called by muse, mutect2, varscan2
- ADAMTS12 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100711673; called by muse, mutect2, varscan2
- ADAMTS6 | c.630G>T p.S210= | Splice Region (SNP) | VAF 18/70 reads (26%) | catalogued as COSV66859520; called by mutect2, varscan2
- ADGRB3 | c.2597C>A p.P866H | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99483595; called by muse, mutect2, varscan2
- ADGRG4 | c.7996C>A p.P2666T | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1415732873; called by muse, mutect2, varscan2
- ADH1B | c.570C>T p.V190= | Splice Region (SNP) | VAF 67/144 reads (47%) | catalogued as COSV100520812; called by muse, mutect2, varscan2
- ADM | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.404); catalogued as COSV53402822, COSV99534241; called by muse, mutect2, varscan2
- AFF2 | c.3267G>T p.L1089= | Splice Region (SNP) | VAF 26/72 reads (36%) | catalogued as rs782088318, COSV53997652; called by muse, mutect2, varscan2
- AFG1L | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV64555826; called by muse, mutect2
- AGBL1 | c.376C>A p.R126S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV69800923; called by muse, mutect2, varscan2
- AGBL1 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.847); catalogued as COSV69815425; called by muse, mutect2, varscan2
- AHI1 | c.2107G>T p.A703S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV55634086; called by muse, varscan2
- AHNAK2 | c.2797G>T p.G933C | Missense Mutation (SNP) | VAF 131/203 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1480638407; called by muse, varscan2
- AKAP4 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.973); catalogued as COSV62073730; called by muse, mutect2, varscan2
- AKNA | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1186515675; called by muse, mutect2, varscan2
- AKR1C4 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as rs1554798103; called by muse, mutect2, varscan2
- ALDH1L2 | c.2486C>A p.P829H | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311208; called by muse, mutect2, varscan2
- ALK | c.1142del p.P381Qfs*42 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | catalogued as COSV66583509; called by mutect2, pindel, varscan2
- ANK2 | c.11848G>A p.E3950K | Missense Mutation (SNP) | VAF 231/393 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs746413508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.12866G>C p.G4289A (on ENST00000280772 / NM_001320874.2; = p.G913A on NM_001149.3) | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.189); catalogued as COSV55069134; called by muse, mutect2, varscan2
- ANKRD30A | c.678G>T p.Q226H (on ENST00000611781; = p.Q170H on NM_052997.2) | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV64612865; called by muse, mutect2, varscan2
- ANKRD7 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99500940; called by muse, mutect2, varscan2
- AOAH | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs750221911; called by muse, mutect2, varscan2
- AP1B1 | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV100434777; called by muse, mutect2, varscan2
- APC | c.4304G>C p.R1435T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57331063, COSV57332751; called by muse, mutect2, varscan2
- APCS | c.175T>C p.Y59H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs767855061; called by muse, mutect2, varscan2
- ARAP2 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV58288508; called by muse, mutect2, varscan2
- ARID1B | c.3442G>T p.E1148* | Nonsense Mutation (SNP) | VAF 69/170 reads (41%) | catalogued as rs1554231873, CM1314076, COSV99266777; called by muse, mutect2, varscan2
- ARMC5 | c.1997G>T p.R666L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51656895; called by muse, mutect2, varscan2
- ARRB1 | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs373898995; called by muse, varscan2
- ASB3 | c.28A>T p.T10S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.562); catalogued as COSV54858868; called by muse, mutect2, varscan2
- ASTN1 | c.3445G>T p.D1149Y | Missense Mutation (SNP) | VAF 139/274 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62500465; called by muse, mutect2, varscan2
- ASTN2 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); catalogued as COSV57761242; called by muse, mutect2, varscan2
- ASXL3 | c.5377G>C p.E1793Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV52484198, COSV99325087; called by muse, mutect2, varscan2
- ATF7IP | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV99661398; called by muse, mutect2, varscan2
- ATP2B3 | c.761C>A p.S254* | Nonsense Mutation (SNP) | VAF 107/278 reads (38%) | catalogued as COSV54856977; called by muse, mutect2, varscan2
- ATR | c.4551G>C p.M1517I | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63386860; called by muse, mutect2, varscan2
- AURKB | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1322292985, COSV60243500; called by muse, mutect2, varscan2
- B3GAT2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57768417; called by muse, mutect2, varscan2
- BAZ2B | c.4915G>C p.G1639R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs746499486; called by muse, mutect2, varscan2
- BCORL1 | c.2096C>A p.P699Q | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.342); catalogued as COSV99500522; called by muse, mutect2, varscan2
- BEX4 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); catalogued as COSV101015391; called by muse, varscan2
- BMPR1B | c.1422G>T p.W474C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52780984; called by muse, mutect2, varscan2
- BTBD11 | c.1648G>T p.D550Y (on ENST00000280758 / NM_001018072.2; = p.D87Y on NM_001017523.2) | Missense Mutation (SNP) | VAF 83/109 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99775572; called by muse, varscan2
- BTK | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as CM056547, COSV100437965; called by muse, mutect2, varscan2
- C10orf82 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.445); catalogued as rs144390968; called by muse, mutect2, varscan2
- C1orf94 | c.898C>A p.R300S (on ENST00000488417 / NM_001134734.2; = p.R110S on NM_032884.5) | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs367889351; called by muse, mutect2
- C3AR1 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369192; called by muse, mutect2, varscan2
- C9 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV54679485; called by muse, mutect2, varscan2
- C9orf43 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1294183949, COSV55913186; called by muse, mutect2, varscan2
- CACNA1F | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249437161, CM021523; called by muse, mutect2, varscan2
- CACNA1G | c.3662G>A p.G1221E | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100662216; called by muse, mutect2, varscan2
- CACNA1S | c.5177T>C p.L1726P | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); catalogued as COSV62941878; called by muse, mutect2, varscan2
- CACNG3 | c.943del p.V315Sfs*40 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV50064727; called by mutect2, pindel
- CADPS | c.1844G>T p.W615L | Missense Mutation (SNP) | VAF 81/149 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1263467757; called by muse, mutect2, varscan2
- CALCR | c.764G>T p.C255F (on ENST00000649521 / NM_001164737.2; = p.C239F on NM_001742.4) | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64012066; called by muse, mutect2, varscan2
- CARD11 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV67797079; called by muse, mutect2, varscan2
- CC2D2A | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV67505125; called by muse, mutect2, varscan2
- CCDC102B | c.1196G>T p.R399I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs752772703; called by muse, mutect2, varscan2
- CCDC158 | c.3158-1G>T p.X1053_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV66355120; called by muse, mutect2
- CCDC27 | c.58del p.E20Kfs*190 | Frame Shift Del (DEL) | VAF 78/189 reads (41%) | catalogued as COSV53899703, COSV53904013; called by mutect2, pindel, varscan2
- CCDC74B | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 102/316 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99064177; called by muse, mutect2, varscan2
- CCDC91 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765168332; called by muse, mutect2, varscan2
- CD163L1 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 87/124 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1189250280; called by muse, mutect2, varscan2
- CD300LB | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761612833; called by muse, mutect2, varscan2
- CDH12 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 52/155 reads (34%) | catalogued as COSV66447674; called by muse, mutect2, varscan2
- CDH23 | c.611C>A p.T204K | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as COSV54930056; called by muse, mutect2, varscan2
- CDH8 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV54858945; called by muse, mutect2, varscan2
- CDHR1 | c.553C>A p.R185S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.804); catalogued as COSV100259467; called by muse, mutect2, varscan2
- CENPE | c.7598G>T p.G2533V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54384042; called by muse, mutect2, varscan2
- CHAT | c.1249G>C p.G417R | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM105868, COSV60321866, COSV60328063; called by muse, mutect2, varscan2
- CHD7 | c.6376G>C p.D2126H | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs1162346018; called by muse, mutect2, varscan2
- CHMP3 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV55686043; called by muse, mutect2, varscan2
- CHPF | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV99704588; called by muse, mutect2, varscan2
- CHRD | c.2452G>T p.G818W | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52608899; called by muse, mutect2, varscan2
- CLCN5 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782676621, COSV56585041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLUL1 | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs371155784; called by muse, mutect2, varscan2
- CMYA5 | c.7025A>T p.D2342V | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs372139811; called by muse, mutect2, varscan2
- CNTN1 | c.3054C>A p.F1018L | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.899); catalogued as COSV61636041; called by muse, mutect2, varscan2
- CNTNAP4 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV56696542; called by muse, mutect2, varscan2
- CNTNAP5 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs774298612, COSV101443070; called by muse, mutect2, varscan2
- COL12A1 | c.8222G>T p.C2741F | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1269744948; called by muse, mutect2, varscan2
- COL15A1 | c.1165A>G p.M389V | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767448137; called by muse, mutect2, varscan2
- COL22A1 | c.2589G>T p.M863I | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.156); catalogued as COSV57333667; called by muse, mutect2
- COL4A5 | c.3627A>T p.L1209F | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60368397; called by muse, mutect2, varscan2
- COL5A3 | c.2314G>T p.A772S | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as COSV99318369; called by muse, mutect2, varscan2
- COL6A1 | c.2444G>T p.C815F | Missense Mutation (SNP) | VAF 113/167 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs536370523; called by muse, mutect2, varscan2
- COL9A1 | c.1068C>A p.G356= | Splice Region (SNP) | VAF 36/140 reads (26%) | catalogued as rs768608047; called by muse, varscan2
- COLEC12 | c.2110C>A p.P704T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1210835273; called by muse, mutect2, varscan2
- CPLANE1 | c.9569C>G p.S3190C | Missense Mutation (SNP) | VAF 50/317 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs781448726, COSV99951320; called by muse, mutect2, varscan2
- CPS1 | c.3222G>T p.K1074N | Missense Mutation (SNP) | VAF 137/441 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99243203; called by muse, mutect2, varscan2
- CPT1C | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1027447826, COSV54920671; called by muse, mutect2, varscan2
- CPXM2 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV53870772; called by muse, mutect2, varscan2
- CSMD3 | c.11024C>G p.A3675G (on ENST00000297405 / NM_001363185.1; = p.A3506G on NM_052900.3) | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV99838317; called by muse, mutect2, varscan2
- CSMD3 | c.354C>A p.Y118* | Nonsense Mutation (SNP) | VAF 53/133 reads (40%) | catalogued as COSV52125086; called by muse, mutect2, varscan2
- CSMD3 | c.13C>A p.R5S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as rs1276765555, COSV52176756; called by muse, mutect2, varscan2
- CST8 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs770388384; called by muse, varscan2
- CST9 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.076); catalogued as rs1333492862; called by muse, mutect2, varscan2
- CSTF2 | c.1653G>T p.Q551H | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100880844; called by muse, mutect2, varscan2
- CTNNA3 | c.1571C>A p.A524D | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101050979; called by muse, mutect2, varscan2
- CUBN | c.7586G>A p.S2529N | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs886046868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DACH1 | c.1816C>A p.P606T (on ENST00000619232 / NM_001366712.1; = p.P352T on NM_004392.6) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV57492586; called by muse, mutect2, varscan2
- DBF4 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.079); catalogued as rs757318189; called by muse, mutect2, varscan2
- DBX2 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as rs750113512; called by muse, mutect2, varscan2
- DCAF12L2 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 145/422 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV63583746; called by muse, mutect2, varscan2
- DCAF8L1 | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as rs148833488; called by muse, mutect2, varscan2
- DCC | c.3398G>C p.R1133P | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71433463, COSV71436709; called by muse, mutect2, varscan2
- DCLK1 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV99714001; called by muse, mutect2, varscan2
- DCX | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV57574246; called by muse, mutect2, varscan2
- DDX31 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1038638187; called by muse, mutect2, varscan2
- DEFB113 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100435371; called by muse, mutect2, varscan2
- DENND2A | c.1521G>T p.M507I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52050410; called by muse, mutect2, varscan2
- DISC1 | c.1240G>C p.A414P | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV54403737; called by muse, mutect2, varscan2
- DKC1 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 211/517 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101059876; called by muse, mutect2, varscan2
- DLGAP2 | c.1188C>A p.H396Q | Missense Mutation (SNP) | VAF 83/137 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.293); catalogued as COSV101423213; called by muse, mutect2, varscan2
- DNAH5 | c.10870C>T p.Q3624* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs1295167678; called by muse, mutect2, varscan2
- DNAH7 | c.6508A>T p.T2170S | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417787; called by muse, mutect2, varscan2
- DNAH9 | c.3809C>A p.S1270Y | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV52378120, COSV99308529; called by muse, mutect2, varscan2
- DNAH9 | c.8708G>C p.G2903A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV99304563; called by muse, mutect2, varscan2
- DNAI4 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs911642117; called by muse, mutect2, varscan2
- DOCK2 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 95/169 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99909750; called by muse, mutect2, varscan2
- DOCK2 | c.3566G>T p.R1189L | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV56980880; called by muse, mutect2, varscan2
- DOK2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs867550583, COSV52387505; called by muse, mutect2, varscan2
- DPEP3 | c.438C>A p.C146* | Nonsense Mutation (SNP) | VAF 32/156 reads (21%) | catalogued as COSV99262794; called by muse, mutect2, varscan2
- DPP6 | c.1620C>A p.S540R (on ENST00000377770 / NM_001364500.2; = p.S478R on NM_001936.5) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV100127928; called by muse, mutect2, varscan2
- DSG1 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 140/317 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936101; called by muse, mutect2, varscan2
- DUOX2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200434528, COSV50993149; called by muse, varscan2
- DYTN | c.1401C>A p.S467R | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs776107210; called by muse, mutect2, varscan2
- DZANK1 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1329165605; called by muse, mutect2, varscan2
- EBF1 | c.1397C>A p.S466* | Nonsense Mutation (SNP) | VAF 93/216 reads (43%) | catalogued as COSV58173064; called by muse, mutect2, varscan2
- ECM2 | c.1742C>A p.P581Q | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60738888; called by muse, mutect2, varscan2
- EDNRB | c.296G>C p.G99A (on ENST00000377211 / NM_001201397.1; = p.G9A on NM_000115.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100526670; called by muse, mutect2, varscan2
- EFCAB3 | c.677T>A p.L226H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV59503577; called by muse, mutect2, varscan2
- EFCAB6 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs565223062; called by muse, mutect2, varscan2
- EGR1 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV99525560; called by muse, mutect2, varscan2
- EHMT1 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV58381860; called by muse, varscan2
- EPHA5 | c.2684A>G p.Y895C | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762405593; called by muse, mutect2, varscan2
- EPHA5 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.432); catalogued as rs778192399, COSV56647899; called by muse, mutect2, varscan2
- EPO | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99079054; called by muse, varscan2
- ERBB4 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53585637; called by muse, mutect2, varscan2
- ESF1 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs1405804941; called by muse, mutect2, varscan2
- EVX1 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1193490321; called by muse, mutect2, varscan2
- EXOC1 | c.2084G>T p.R695L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62119004; called by muse, mutect2, varscan2
- EYS | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV60977174, COSV60983569; called by muse, mutect2, varscan2
- EZHIP | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1409790671; called by muse, varscan2
- EZHIP | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782314957; called by muse, varscan2
- F11R | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231130; called by muse, mutect2, varscan2
- F2RL1 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV56995029; called by muse, mutect2, varscan2
- F8 | c.3749G>T p.S1250I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV64275242; called by muse, mutect2, varscan2
- FADS6 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV59604129; called by muse, mutect2, varscan2
- FAM135B | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV99428538; called by muse, mutect2, varscan2
- FAM13C | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.962); catalogued as COSV53248106; called by muse, mutect2, varscan2
- FAM47C | c.1626C>A p.S542R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV63727594; called by muse, mutect2, varscan2
- FAM71F2 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV101100653, COSV101100726; called by muse, mutect2, varscan2
- FAM83H | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as COSV66353866; called by muse, varscan2
- FAM9A | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 32/48 reads (67%) | catalogued as rs377667696; called by muse, mutect2, varscan2
- FAT1 | c.8496G>T p.R2832S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV101499591; called by muse, mutect2, varscan2
- FAT1 | c.8495G>T p.R2832M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV71675702; called by muse, mutect2, varscan2
- FAT4 | c.10055A>T p.K3352M | Missense Mutation (SNP) | VAF 82/134 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as COSV58681601, COSV58686093; called by muse, mutect2, varscan2
- FCSK | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs528370718; called by muse, mutect2, varscan2
- FGF3 | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61925162, COSV61926127; called by muse, mutect2, varscan2
- FLG | c.4295G>T p.G1432V | Missense Mutation (SNP) | VAF 110/417 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV64244057; called by muse, mutect2, varscan2
- FMN1 | c.2222A>T p.Q741L (on ENST00000616417 / NM_001277313.2; = p.Q518L on NM_001103184.4) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57927079; called by muse, mutect2, varscan2
- FMN2 | c.3676C>A p.P1226T | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.456); catalogued as rs1216046981, COSV60440194; called by muse, mutect2, varscan2
- FOXP2 | c.1263A>T p.K421N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV63488991; called by muse, mutect2, varscan2
- FPR2 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60671943, COSV60674019; called by muse, mutect2, varscan2
- FRMD7 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM128439; called by muse, mutect2, varscan2
- FRMPD3 | c.4016G>T p.R1339L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs761809395, COSV52187850; called by muse, mutect2, varscan2
- FXYD2 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs139816783; called by muse, mutect2, varscan2
- G6PD | c.520G>C p.G174R | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100855009; called by muse, mutect2, varscan2
- GABRG1 | c.843C>A p.C281* | Nonsense Mutation (SNP) | VAF 50/154 reads (32%) | catalogued as COSV54950697; called by muse, mutect2, varscan2
- GALNT8 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV52898489; called by muse, mutect2, varscan2
- GC | c.857G>A p.C286Y | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459492256; called by muse, mutect2, varscan2
- GDA | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52990110; called by mutect2, varscan2
- GDF9 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs780122787, COSV51526444; called by muse, mutect2, varscan2
- GNL3L | c.1667-1G>C p.X556_splice | Splice Site (SNP) | VAF 19/98 reads (19%) | catalogued as COSV60577361; called by muse, mutect2, varscan2
- GPC5 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); catalogued as rs769981633; called by muse, varscan2
- GPC5 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs372954675; called by muse, mutect2, varscan2
- GPLD1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs139020496; called by muse, mutect2, varscan2
- GPR158 | c.1188G>T p.R396S | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV66267232; called by muse, mutect2, varscan2
- GPR158 | c.1606G>T p.V536L | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.09); catalogued as rs756309777; called by muse, varscan2
- GPR158 | c.2540C>A p.S847Y | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66274564; called by muse, mutect2, varscan2
- GPR183 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs745900708; called by mutect2, varscan2
- GPR61 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs951217511; called by muse, mutect2, varscan2
- GPRC6A | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767566797; called by muse, mutect2, varscan2
- GPX8 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432060594; called by muse, mutect2, varscan2
- GRIK1 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 64/92 reads (70%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV58718271; called by muse, mutect2, varscan2
- GRIPAP1 | c.231G>C p.M77I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV64553216; called by muse, mutect2, varscan2
- GRM8 | c.915G>T p.W305C | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58878012; called by muse, varscan2
- GRM8 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 100/235 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs371903212; called by muse, mutect2, varscan2
- HCN1 | c.2496G>T p.R832S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as rs267600644, COSV57500191, COSV57534251; called by muse, mutect2, varscan2
- HEATR6 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV51744021, COSV51745822; called by muse, mutect2, varscan2
- HEXD | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs749879786, COSV60066080; called by muse, mutect2, varscan2
- HGD | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs756737699, COSV52202187; called by muse, mutect2, varscan2
- HGF | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV55948501; called by muse, mutect2, varscan2
- HGF | c.900G>T p.L300F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV99736888; called by muse, mutect2, varscan2
- HOXD13 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs911459139; called by muse, mutect2, varscan2
- HOXD8 | c.777C>A p.D259E | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs867464783; called by muse, mutect2, varscan2
- HS3ST2 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as rs866604120, COSV99758612; called by muse, mutect2, varscan2
- HS3ST2 | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99757658; called by muse, mutect2, varscan2
- HS3ST3A1 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV52375145; called by muse, varscan2
- HSD17B4 | c.205G>T p.D69Y (on ENST00000414835 / NM_001199291.3; = p.D44Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as CD060117; called by muse, mutect2, varscan2
- HSD17B7 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs373109770; called by muse, mutect2, varscan2
- HTN1 | c.102T>C p.H34= | Splice Region (SNP) | VAF 17/99 reads (17%) | catalogued as rs776856139; called by muse, mutect2, varscan2
- HTR2A | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs763386955; called by muse, mutect2, varscan2
- HUWE1 | c.12857G>A p.R4286H | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs782290958, COSV104394403; called by muse, mutect2, varscan2
- ICE1 | c.1519G>T p.G507C | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs1322544389; called by muse, mutect2, varscan2
- ICE1 | c.2911A>T p.I971F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV99664622; called by muse, mutect2, varscan2
- ICE1 | c.6031C>G p.R2011G | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56831396; called by muse, mutect2, varscan2
- IDE | c.1870A>G p.I624V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1277293098; called by muse, mutect2, varscan2
- IDH3G | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99473417; called by muse, mutect2, varscan2
- IDS | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61711829; called by muse, mutect2, varscan2
- IGFBP1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51874611, COSV51874856; called by muse, mutect2, varscan2
- IGFBP6 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 75/111 reads (68%) | catalogued as rs770394224, COSV100037124, COSV56857324; called by muse, mutect2, varscan2
- IGKV4-1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs758328657; called by muse, varscan2
- ILDR2 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54830741; called by muse, mutect2, varscan2
- INHBA | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1030538647; called by muse, mutect2, varscan2
- INO80 | c.4654C>T p.P1552S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs545022339; called by muse, mutect2, varscan2
- INSC | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 54/135 reads (40%) | catalogued as rs748096504; called by muse, mutect2, varscan2
- INTS6L | c.190-1G>T p.X64_splice | Splice Site (SNP) | VAF 44/124 reads (35%) | catalogued as COSV100878299; called by muse, varscan2
- IQSEC2 | c.2032G>T p.G678C (on ENST00000642864 / NM_001111125.3; = p.G473C on NM_015075.2) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100944806; called by muse, mutect2, varscan2
- IRX6 | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99306666; called by muse, mutect2, varscan2
- ITGA10 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1446305231; called by muse, mutect2, varscan2
- ITGB8 | c.1730G>C p.G577A | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV56008462; called by muse, mutect2, varscan2
- ITIH2 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623125; called by muse, mutect2, varscan2
- ITIH5 | c.1225C>G p.P409A | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as COSV99903552; called by muse, mutect2, varscan2
- ITIH5 | c.671del p.P224Hfs*14 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as COSV53671524; called by mutect2, pindel, varscan2
- KALRN | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53756046; called by muse, mutect2, varscan2
- KCNJ2 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54660564; called by muse, mutect2, varscan2
- KCNK16 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV64678124; called by muse, mutect2, varscan2
- KCNK18 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100571980, COSV57973523; called by muse, mutect2, varscan2
- KCNMB1 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1361499360; called by muse, mutect2, varscan2
- KCNMB2 | c.136del p.R46Efs*9 | Frame Shift Del (DEL) | VAF 82/172 reads (48%) | catalogued as COSV100844014; called by mutect2, varscan2
- KCNT1 | c.1441G>T p.V481F (on ENST00000488444; = p.V500F on NM_020822.3) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV53704801; called by muse, mutect2, varscan2
- KCTD16 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV101568895; called by muse, mutect2, varscan2
- KDM5B | c.2247G>T p.K749N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs867259883; called by muse, mutect2, varscan2
- KEL | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs150678405; called by muse, mutect2, varscan2
- KHDRBS2 | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs766702570, COSV55456089, COSV55485790; called by muse, mutect2
- KIF1A | c.4826G>T p.R1609L (on ENST00000320389 / NM_001379639.1; = p.R1601L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57488181; called by muse, mutect2, varscan2
- KIF25 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs138311357; called by muse, mutect2, varscan2
- KIF26B | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.765); catalogued as rs1490451180; called by muse, mutect2
- KIF26B | c.3077C>A p.P1026Q | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.689); catalogued as rs780567755, CM1410416; called by muse, varscan2
- KIF2B | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs751730942; called by muse, mutect2
- KIFAP3 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs1010234068, COSV63038426; called by muse, mutect2, varscan2
- KLF8 | c.6C>A p.V2= | Splice Region (SNP) | VAF 19/93 reads (20%) | catalogued as rs779516670, COSV100808227; called by muse, mutect2, varscan2
- KLHL1 | c.2151G>T p.M717I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV64773291; called by muse, mutect2, varscan2
- KLHL25 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs774483590, COSV100563608; called by muse, mutect2, varscan2
- KRT20 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99071865; called by mutect2, varscan2
- KRTAP15-1 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 75/105 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV61876948, COSV61877024; called by muse, mutect2, varscan2
- LAMA2 | c.6323G>T p.R2108L | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV70339232; called by muse, mutect2, varscan2
- LAMB3 | c.2585A>G p.Q862R | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs746900366; called by muse, mutect2, varscan2
- LAMB3 | c.2476G>T p.G826C | Missense Mutation (SNP) | VAF 197/397 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs763401881; called by muse, mutect2, varscan2
- LAMB4 | c.4329C>A p.I1443= | Splice Region (SNP) | VAF 11/35 reads (31%) | catalogued as rs759845181; called by muse, mutect2, varscan2
- LAMP5 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV99855501; called by mutect2, varscan2
- LANCL2 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs371096573; called by muse, mutect2, varscan2
- LARGE1 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 115/172 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61670284; called by muse, mutect2, varscan2
- LAX1 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV65850321; called by muse, mutect2, varscan2
- LGR5 | c.1360C>G p.H454D | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV57004102; called by muse, mutect2, varscan2
- LOXL2 | c.1151-1G>A p.X384_splice | Splice Site (SNP) | VAF 32/105 reads (30%) | catalogued as rs1280632002; called by muse, mutect2, varscan2
- LRATD1 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs745791726; called by muse, mutect2, varscan2
- LRP1B | c.11153C>A p.T3718K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.375); catalogued as COSV99068975; called by muse, mutect2, varscan2
- LRRC7 | c.3838G>A p.D1280N (on ENST00000651989 / NM_001370785.2; = p.D1247N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV99230681; called by muse, mutect2, varscan2
- LRRTM1 | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54439970, COSV54440997; called by muse, mutect2, varscan2
- LUZP4 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs781918038, COSV100904879, COSV64219278; called by muse, mutect2, varscan2
- LYST | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 122/236 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as rs1241284431, COSV67707333; called by muse, mutect2
- LYST | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV101089135; called by muse, mutect2, varscan2
- MAGEB6 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs775425014; called by muse, mutect2, varscan2
- MAGEB6B | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV69689992; called by muse, mutect2, varscan2
- MANBA | c.2239A>G p.T747A (on ENST00000642252; = p.T701A on NM_005908.4) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs113843904; called by muse, mutect2, varscan2
- MARF1 | c.144G>C p.T48= | Splice Region (SNP) | VAF 34/82 reads (41%) | catalogued as COSV60026113; called by muse, mutect2, varscan2
- MARK3 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs768452348; called by muse, mutect2, varscan2
- MDGA2 | c.2741G>C p.G914A (on ENST00000399232 / NM_001113498.2; = p.G616A on NM_182830.4) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1226592054, COSV100637351; called by muse, mutect2, varscan2
- MEGF10 | c.1810C>G p.P604A | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as rs202135671; called by muse, mutect2, varscan2
- MFN1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54939778; called by muse, mutect2, varscan2
- MGAM | c.5518G>A p.D1840N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1464994716; called by muse, mutect2, varscan2
- MME | c.1740G>T p.M580I | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV64706965; called by muse, mutect2, varscan2
- MMS22L | c.3421G>A p.V1141I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV99245868; called by muse, mutect2, varscan2
- MORC1 | c.672G>T p.M224I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99226438; called by muse, mutect2, varscan2
- MORN5 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV65649742; called by muse, mutect2, varscan2
- MRC1 | c.1634G>C p.R545T | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1405512882; called by muse, varscan2
- MTCP1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV62899234; called by muse, varscan2
- MTM1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as CD991802; called by muse, mutect2, varscan2
- MTNR1A | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100208235; called by muse, varscan2
- MTUS2 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV70916672; called by muse, mutect2, varscan2
- MUC5B | c.11457G>T p.M3819I | Missense Mutation (SNP) | VAF 233/487 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1043799729; called by muse, mutect2, varscan2
- MYH3 | c.4841G>T p.R1614L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56867826; called by muse, mutect2, varscan2
- MYL10 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781235; called by muse, mutect2, varscan2
- MYO3A | c.3362A>T p.Q1121L | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV56341437; called by muse, mutect2, varscan2
- MYO7B | c.3027C>A p.A1009= | Splice Region (SNP) | VAF 32/150 reads (21%) | catalogued as rs202235279, COSV67345147; called by muse, mutect2, varscan2
- MYOCD | c.1421C>A p.T474N | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs1450031224; called by muse, mutect2, varscan2
- MYOM2 | c.2796C>A p.C932* | Nonsense Mutation (SNP) | VAF 35/153 reads (23%) | catalogued as rs747211012; called by muse, mutect2, varscan2
- MYRF | c.382G>T p.A128S (on ENST00000278836 / NM_001127392.3; = p.A119S on NM_013279.4) | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV99606801; called by muse, mutect2, varscan2
- NALCN | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213220; called by muse, mutect2, varscan2
- NDST4 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 60/97 reads (62%) | catalogued as COSV52135208; called by muse, mutect2, varscan2
- NETO1 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV55002433, COSV55009619; called by muse, mutect2, varscan2
- NID2 | c.2945G>T p.W982L | Missense Mutation (SNP) | VAF 106/165 reads (64%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV99357144; called by muse, mutect2, varscan2
- NKAIN2 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs1209288973; called by muse, mutect2, varscan2
- NLRP1 | c.3163G>T p.E1055* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV52565143; called by muse, mutect2, varscan2
- NLRP5 | c.1731G>C p.E577D | Missense Mutation (SNP) | VAF 73/131 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as COSV101173387; called by muse, mutect2, varscan2
- NLRP7 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV60180642; called by muse, mutect2
- NLRP8 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV52588166; called by muse, mutect2, varscan2
- NLRP8 | c.1282G>T p.V428F | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- NOL8 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62637363; called by muse, varscan2
- NOS1AP | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62636030; called by muse, mutect2, varscan2
- NPY1R | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as COSV56716992; called by muse, mutect2, varscan2
- NRK | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99686415; called by muse, mutect2, varscan2
- NRK | c.3431C>G p.S1144C | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV54603190; called by muse, mutect2, varscan2
- NRK | c.4558A>G p.I1520V | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1205785066; called by muse, mutect2, varscan2
- NRXN2 | c.4586C>T p.P1529L | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV55460553; called by muse, mutect2, varscan2
- NTM | c.988G>T p.V330F | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.082); catalogued as COSV66205600; called by muse, mutect2, varscan2
- NTRK3 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs751051788, COSV58109641; called by muse, mutect2
- OBSCN | c.12856G>T p.G4286* | Nonsense Mutation (SNP) | VAF 89/334 reads (27%) | catalogued as COSV52783069; called by muse, mutect2, varscan2
- OLFML2B | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54198864; called by muse, mutect2, varscan2
- OR10S1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV73343021; called by muse, mutect2, varscan2
- OR10T2 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV57782414; called by muse, mutect2, varscan2
- OR11L1 | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 124/311 reads (40%) | catalogued as rs201677584; called by muse, mutect2, varscan2
- OR1S2 | c.977G>C p.*326Sext*? | Nonstop Mutation (SNP) | VAF 62/97 reads (64%) | catalogued as COSV100224049; called by muse, mutect2, varscan2
- OR2C3 | c.900C>G p.S300R | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63574946; called by muse, mutect2, varscan2
- OR2F1 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 208/392 reads (53%) | catalogued as COSV67332171; called by muse, varscan2
- OR2G3 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs200831993, COSV60681098; called by muse, varscan2
- OR2L13 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63551973; called by muse, mutect2, varscan2
- OR2L13 | c.714del p.T239Pfs*6 | Frame Shift Del (DEL) | VAF 64/170 reads (38%) | catalogued as COSV100813796; called by pindel, varscan2
- OR2L2 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV63558414; called by muse, mutect2, varscan2
- OR2M2 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV62899590; called by muse, mutect2, varscan2
- OR2M5 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV63546511; called by muse, mutect2, varscan2
- OR2T10 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1375160354, COSV57896746; called by muse, mutect2, varscan2
- OR2T6 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63217115; called by mutect2, varscan2
- OR4C11 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs753075282, COSV56354751; called by muse, mutect2, varscan2
- OR4C46 | c.546G>T p.L182F | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.658); catalogued as rs747017403, COSV60219877; called by muse, varscan2
- OR4C6 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs139660252, COSV58603441, COSV58605175; called by muse, mutect2, varscan2
- OR5AC2 | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV62279339; called by muse, mutect2, varscan2
- OR5B2 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 77/122 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV56908998; called by muse, mutect2, varscan2
- OR5D16 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV65722021; called by muse, mutect2, varscan2
- OR5W2 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100747516; called by muse, mutect2, varscan2
- OR6K2 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV62743696; called by muse, mutect2, varscan2
- OR8A1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99420554; called by muse, mutect2, varscan2
- OR8U1 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100163799; called by muse, varscan2
- OR9A2 | c.293C>A p.S98* | Nonsense Mutation (SNP) | VAF 89/358 reads (25%) | catalogued as COSV63306321; called by muse, mutect2, varscan2
- OTOP2 | c.1126G>C p.A376P | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58881441, COSV58882739; called by muse, mutect2, varscan2
- OTOS | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376456799; called by muse, mutect2, varscan2
- OTUD6A | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 138/241 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57974035; called by muse, mutect2, varscan2
- PAPPA2 | c.666G>T p.W222C | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV100867271; called by muse, mutect2, varscan2
- PARVG | c.920G>T p.R307M | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63561704, COSV63562271; called by muse, mutect2, varscan2
- PAX4 | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.598); catalogued as COSV58390648; called by muse, mutect2, varscan2
- PAX4 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as COSV58387591; called by muse, mutect2, varscan2
- PCDH15 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57378887; called by muse, mutect2, varscan2
- PCDH17 | c.1789G>T p.V597L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.897); catalogued as COSV64976287; called by mutect2, varscan2
- PCDH17 | c.2080C>G p.R694G | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as rs776873573, COSV100931611; called by muse, mutect2, varscan2
- PCDH9 | c.3199G>T p.G1067C (on ENST00000377865 / NM_203487.3; = p.G1033C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60524774; called by muse, mutect2, varscan2
- PCDHA2 | c.1741G>C p.V581L | Missense Mutation (SNP) | VAF 89/381 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.116); catalogued as COSV65367947; called by muse, mutect2, varscan2
- PCDHA8 | c.2329C>A p.P777T | Missense Mutation (SNP) | VAF 92/447 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as COSV100970189; called by muse, mutect2, varscan2
- PCDHB10 | c.1377C>A p.F459L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.02); catalogued as COSV53375844; called by muse, mutect2, varscan2
- PCDHB13 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 178/403 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as rs1554287992, COSV53400807; called by muse, mutect2, varscan2
- PCDHB4 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.232); catalogued as rs1185586111, COSV99522521; called by muse, mutect2, varscan2
- PCDHGA5 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs372313739; called by muse, mutect2, varscan2
- PCDHGA9 | c.823G>C p.G275R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99038274, COSV99531367; called by muse, mutect2, varscan2
- PCYOX1L | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99199194; called by muse, mutect2, varscan2
- PDE10A | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV63102009; called by muse, mutect2, varscan2
- PDE3A | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 24/36 reads (67%) | catalogued as COSV100761437; called by muse, mutect2, varscan2
- PDE4DIP | c.5695C>G p.Q1899E | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV57691881; called by muse, mutect2, varscan2
- PDE4DIP | c.6814G>T p.G2272* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100520858; called by muse, mutect2, varscan2
- PER3 | c.1269C>A p.Y423* | Nonsense Mutation (SNP) | VAF 132/272 reads (49%) | catalogued as rs140055805; called by muse, mutect2, varscan2
- PGRMC1 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54292527; called by muse, mutect2, varscan2
- PHACTR3 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV100732582; called by muse, mutect2, varscan2
- PHF1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.048); catalogued as COSV65702451; called by muse, mutect2, varscan2
- PIGU | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.298); catalogued as rs1346592984; called by muse, mutect2
- PIPOX | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100037920; called by muse, mutect2, varscan2
- PITPNM1 | c.2146G>T p.A716S | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.039); catalogued as COSV62709639, COSV62709954; called by muse, mutect2
- PKHD1 | c.2797G>T p.V933F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV61887806; called by muse, mutect2, varscan2
- PKHD1L1 | c.9935G>T p.R3312M | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as COSV101006624; called by muse, mutect2, varscan2
- PLPPR4 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1195753337; called by muse, mutect2, varscan2
- PLPPR4 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64567889; called by muse, mutect2, varscan2
- PLPPR4 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 112/228 reads (49%) | catalogued as COSV64566718, COSV64567471; called by muse, mutect2, varscan2
- PLXNB3 | c.2140C>A p.L714M | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV100737252; called by muse, mutect2, varscan2
- PNCK | c.639C>A p.Y213* (on ENST00000340888 / NM_001366975.1; = p.Y296* on NM_001039582.3) | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as COSV61742505; called by muse, mutect2, varscan2
- PNLIP | c.98G>T p.W33L | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65041395, COSV65041992; called by muse, mutect2, varscan2
- PNMA5 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100721596; called by muse, mutect2, varscan2
- POU6F2 | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101302328; called by muse, mutect2
- PPARGC1A | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as rs781331386, COSV99337703; called by muse, mutect2, varscan2
- PPP1R16B | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV55375331, COSV55382060; called by muse, mutect2, varscan2
- PPP2R3B | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 143/255 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.522); catalogued as rs758876575; called by muse, mutect2, varscan2
- PPP3CB | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100646343; called by muse, mutect2, varscan2
- PRDM9 | c.1083C>A p.Y361* | Nonsense Mutation (SNP) | VAF 86/233 reads (37%) | catalogued as COSV57014303; called by muse, mutect2, varscan2
- PRDM9 | c.2240C>A p.P747H | Missense Mutation (SNP) | VAF 110/327 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57006406; called by muse, mutect2, varscan2
- PREX1 | c.3483C>G p.H1161Q | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64251899; called by muse, mutect2, varscan2
- PRKAG2 | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV55243110; called by muse, mutect2, varscan2
- PRKAG3 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs1244477471, COSV99292065; called by muse, mutect2, varscan2
- PRKCQ | c.1180-1G>T p.X394_splice | Splice Site (SNP) | VAF 43/131 reads (33%) | catalogued as COSV54114597; called by muse, mutect2, varscan2
- PRLHR | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 92/354 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV53305484; called by muse, mutect2, varscan2
- PRPF38B | c.1504A>G p.R502G | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs770160975; called by muse, mutect2, varscan2
- PRSS55 | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as rs776707006; called by muse, mutect2, varscan2
- PSMD4 | c.259T>C p.C87R | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs1362335525; called by muse, mutect2, varscan2
- PTPRD | c.1262C>A p.P421Q | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61962769; called by muse, mutect2, varscan2
- PTPRT | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62006180; called by muse, varscan2
- PTPRZ1 | c.900C>G p.Y300* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV66431863; called by muse, mutect2, varscan2
- PUM1 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57083895; called by muse, mutect2, varscan2
- PURG | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53296960; called by muse, mutect2, varscan2
- PXDNL | c.4240T>G p.C1414G | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100687749; called by muse, mutect2, varscan2
- PYROXD2 | c.1717G>C p.V573L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV65329732; called by muse, mutect2, varscan2
- QPCT | c.866T>C p.L289S | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100621677; called by muse, varscan2
- RAB37 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV61197703; called by muse, mutect2, varscan2
- RAB6C | c.101G>T p.R34M | Missense Mutation (SNP) | VAF 66/632 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV69339847; called by muse, mutect2
- RAP2C | c.485G>T p.R162M | Missense Mutation (SNP) | VAF 137/416 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61683511; called by muse, mutect2, varscan2
- RARS2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs779443645; called by mutect2, varscan2
- RBM10 | c.436C>A p.R146S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61308866; called by muse, mutect2, varscan2
- RCSD1 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV63258080; called by muse, mutect2, varscan2
- REG3A | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59408560, COSV59408924, COSV59412149; called by muse, mutect2, varscan2
- RELN | c.5987T>C p.M1996T | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1167906794; called by muse, mutect2, varscan2
- RGS18 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs928628694; called by muse, varscan2
- RGS18 | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs200020460; called by muse, mutect2, varscan2
- RHAG | c.1212+1G>A p.X404_splice | Splice Site (SNP) | VAF 31/78 reads (40%) | catalogued as rs1435209812; called by muse, mutect2, varscan2
- RIMS4 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV65720172; called by muse, mutect2, varscan2
- RIPOR1 | c.3214C>T p.R1072W (on ENST00000379312 / NM_001193522.2; = p.R1068W on NM_024519.4) | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs375623923; called by muse, mutect2, varscan2
- RIPOR1 | c.3215G>T p.R1072L (on ENST00000379312 / NM_001193522.2; = p.R1068L on NM_024519.4) | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV50234978; called by muse, mutect2, varscan2
- RIPPLY3 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV61566969; called by muse, mutect2, varscan2
- ROBO1 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458735; called by muse, mutect2, varscan2
- ROBO2 | c.1350C>A p.S450R | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.89); PolyPhen benign (0.101); catalogued as COSV59901287; called by muse, mutect2, varscan2
- RORB | c.128del p.X43_splice (on ENST00000396204 / NM_001365023.1; = p.X32_splice on NM_006914.4) | Splice Site (DEL) | VAF 12/45 reads (27%) | catalogued as COSV65335208; called by mutect2, pindel, varscan2
- RPTN | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768956118, COSV60167291; called by muse, mutect2, varscan2
- RTL1 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1434788348; called by muse, mutect2, varscan2
- RTL4 | c.272C>A p.A91E | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV100465712; called by muse, mutect2, varscan2
- RYR2 | c.2249G>T p.R750I | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV63710595; called by muse, mutect2, varscan2
- RYR2 | c.12952C>A p.L4318I | Missense Mutation (SNP) | VAF 85/168 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.957); catalogued as COSV63719693; called by muse, mutect2, varscan2
- RYR3 | c.4218C>A p.N1406K | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV66793665; called by muse, varscan2
- SALL4 | c.591C>A p.S197R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs764301551; called by muse, mutect2, varscan2
- SASS6 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs541086017, COSV54927029; called by muse, mutect2, varscan2
- SCN2A | c.2477T>C p.F826S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV51831847; called by muse, varscan2
- SCN9A | c.4599G>T p.M1533I (on ENST00000303354; = p.M1522I on NM_002977.3) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57609747; called by muse, mutect2, varscan2
- SEC31A | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 51/106 reads (48%) | catalogued as COSV100022155; called by muse, varscan2
- SEMA5A | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 101/349 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138343991, COSV66790750; called by muse, mutect2, varscan2
- SEMA5A | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66807644; called by muse, mutect2, varscan2
- SERPINA7 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59666204; called by muse, mutect2, varscan2
- SERPINB7 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV60536603; called by muse, mutect2, varscan2
- SERTAD1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs1313499949; called by muse, mutect2, varscan2
- SGCA | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.402); catalogued as rs958974999, COSV100006737; called by muse, mutect2, varscan2
- SH2D3C | c.2420G>T p.R807L (on ENST00000314830 / NM_170600.3; = p.R650L on NM_005489.4) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs756429820, COSV59130808; called by muse, varscan2
- SHROOM1 | c.1227G>T p.Q409H | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60582800; called by muse, mutect2, varscan2
- SIDT1 | c.982G>T p.G328W | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV53498507; called by muse, mutect2, varscan2
- SIGLEC8 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 100/164 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV58473517; called by muse, mutect2, varscan2
- SIPA1L3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.944); catalogued as rs376921669, COSV99730368; called by muse, mutect2, varscan2
- SLAMF9 | c.520del p.D174Ifs*75 | Frame Shift Del (DEL) | VAF 40/191 reads (21%) | catalogued as rs759108348; called by mutect2, pindel, varscan2
- SLC10A6 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV56721479; called by muse, mutect2, varscan2
- SLC17A2 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.123); catalogued as COSV55353457; called by muse, mutect2, varscan2
- SLC17A6 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54134985; called by muse, mutect2, varscan2
- SLC1A6 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 131/289 reads (45%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.773); catalogued as COSV55669085; called by muse, mutect2, varscan2
- SLC26A3 | c.2224G>C p.D742H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60641493; called by muse, mutect2
- SLC26A3 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100384913, COSV100385279; called by muse, mutect2, varscan2
- SLC38A7 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV54704797; called by muse, mutect2, varscan2
- SLCO6A1 | c.1048C>G p.R350G | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV65805365; called by muse, mutect2, varscan2
- SLFN13 | c.2065C>G p.Q689E | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99539873; called by muse, mutect2, varscan2
- SLIT2 | c.2455C>G p.R819G | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.068); catalogued as COSV56576834; called by muse, mutect2, varscan2
- SLITRK6 | c.1646C>A p.P549H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1422331146; called by muse, mutect2, varscan2
- SMO | c.1102C>G p.P368A | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs374812951, COSV50852845; called by muse, mutect2, varscan2
- SNX7 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1435902751; called by muse, mutect2, varscan2
- SOX2 | c.236G>T p.W79L | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as CM1411079; called by muse, mutect2, varscan2
- SPACA3 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV52192832; called by muse, mutect2, varscan2
- SPATA31A1 | c.1929G>T p.W643C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as rs1177215188; called by mutect2, varscan2
- SPATA31D1 | c.2385G>T p.K795N | Missense Mutation (SNP) | VAF 170/538 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV61201960; called by muse, varscan2
- SPATA46 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.289); catalogued as rs139605225; called by muse, mutect2
- SPHKAP | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs779563361; called by muse, mutect2, varscan2
- SPNS3 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV100336975; called by muse, mutect2, varscan2
- SPON1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59964199; called by muse, mutect2, varscan2
- SPR | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM119168; called by muse, mutect2, varscan2
- SPTA1 | c.6452G>T p.R2151I | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202169454; called by muse, mutect2, varscan2
- SPTA1 | c.5277G>T p.E1759D | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV63755388; called by muse, mutect2, varscan2
- SPTA1 | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV63752353; called by muse, mutect2, varscan2
- SPTBN2 | c.3732C>G p.I1244M | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV59457894; called by muse, varscan2
- ST6GALNAC3 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 83/184 reads (45%) | PolyPhen possibly damaging (0.506); catalogued as COSV100084767, COSV100085804; called by muse, mutect2, varscan2
- STARD3 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs778817399; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2418C>A p.G806= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as COSV59126506; called by muse, mutect2, varscan2
- STYK1 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99030234; called by muse, mutect2, varscan2
- STYXL2 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 107/189 reads (57%) | catalogued as COSV54807664; called by muse, mutect2, varscan2
- STYXL2 | c.2123C>A p.P708H | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV104375854, COSV99609981; called by muse, mutect2, varscan2
- SVEP1 | c.8011C>A p.H2671N | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV52839486; called by muse, mutect2, varscan2
- SYNPO2 | c.3590A>T p.Q1197L | Missense Mutation (SNP) | VAF 62/454 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs766431738; called by muse, mutect2, varscan2
- TAAR5 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as rs188569215; called by muse, varscan2
- TAF4 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs778220814; called by muse, mutect2, varscan2
- TAFA3 | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs538277150; called by mutect2, varscan2
- TBC1D4 | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs774714689; called by muse, mutect2, varscan2
- TBX22 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1296394114; called by mutect2, varscan2
- TCAF1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584736; called by muse, varscan2
- TDRD5 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 82/310 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.145); catalogued as COSV54247095; called by muse, mutect2, varscan2
- TECRL | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV67091663; called by muse, mutect2, varscan2
- TELO2 | c.1363A>G p.T455A | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs764823412; called by muse, mutect2, varscan2
- TENT2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs759860889; called by muse, mutect2, varscan2
- TEX13A | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100781866; called by muse, mutect2, varscan2
- TEX37 | c.289del p.E97Rfs*67 | Frame Shift Del (DEL) | VAF 65/274 reads (24%) | catalogued as COSV100304578; called by mutect2, pindel, varscan2
- TGFB2 | c.646A>C p.R216= | Splice Region (SNP) | VAF 20/149 reads (13%) | catalogued as COSV65108479; called by muse, mutect2, varscan2
- TIAM2 | c.1390C>G p.R464G | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV59691168; called by muse, mutect2, varscan2
- TKTL2 | c.1424G>T p.R475L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs757828647, COSV54917988; called by muse, mutect2, varscan2
- TLE4 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.326); catalogued as COSV54627697; called by muse, mutect2, varscan2
- TMEM132B | c.1711C>A p.R571S | Missense Mutation (SNP) | VAF 171/240 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100171080; called by muse, mutect2, varscan2
- TMEM79 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs748513440; called by muse, mutect2, varscan2
- TMTC1 | c.615G>T p.L205F (on ENST00000539277 / NM_001193451.2; = p.L97F on NM_175861.3) | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); catalogued as rs779107093; called by muse, mutect2, varscan2
- TNN | c.2230T>A p.S744T | Missense Mutation (SNP) | VAF 50/385 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1370105825; called by muse, mutect2, varscan2
- TNN | c.3846G>T p.E1282D | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1310858648; called by muse, mutect2, varscan2
- TOX | c.816T>A p.F272L | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63846560; called by muse, mutect2, varscan2
- TPTE | c.1170G>T p.Q390H (on ENST00000618007 / NM_199261.4; = p.Q372H on NM_199259.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773683205; called by muse, mutect2, varscan2
- TRAPPC12 | c.1441C>G p.R481G | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100161022; called by muse, mutect2, varscan2
- TREX2 | c.239G>T p.R80L (on ENST00000334497; = p.R37L on NM_080701.3) | Missense Mutation (SNP) | VAF 145/412 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100444294, COSV57847905; called by muse, mutect2, varscan2
- TRH | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV57015027; called by muse, mutect2, varscan2
- TRIM58 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63569126; called by muse, mutect2, varscan2
- TRIM75P | c.986del p.P329Qfs*78 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV72295818; called by mutect2, pindel, varscan2
- TRMT9B | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1464801545; called by muse, mutect2, varscan2
- TRPM2 | c.3752C>A p.P1251H | Missense Mutation (SNP) | VAF 156/235 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1231821967; called by muse, mutect2, varscan2
- TRPM6 | c.1564G>T p.G522C | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100667120; called by muse, mutect2, varscan2
- TRPM7 | c.123-1G>T p.X41_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as rs1454837737; called by muse, mutect2, varscan2
- TRPV1 | c.2380G>T p.V794F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1567654618; called by muse, mutect2, varscan2
- TSHZ3 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV53679957; called by muse, mutect2, varscan2
- TTC39C | c.277A>G p.T93A (on ENST00000317571 / NM_001135993.2; = p.T32A on NM_153211.4) | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs776235873; called by muse, mutect2, varscan2
- TTLL5 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as COSV54040520; called by muse, mutect2, varscan2
- TTN | c.76501G>T p.E25501* (on ENST00000591111; = p.E18077* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV60181030, COSV99045784; called by muse, mutect2, varscan2
- TTN | c.75931G>A p.V25311I (on ENST00000591111; = p.V17887I on NM_003319.4) | Missense Mutation (SNP) | VAF 89/263 reads (34%) | PolyPhen benign (0); catalogued as rs371362606; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- UNC45B | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs867823944; called by muse, mutect2, varscan2
- UPK3A | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV53414641; called by muse, mutect2, varscan2
- UROC1 | c.737C>G p.T246S | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.459); catalogued as COSV99330621; called by muse, mutect2, varscan2
- USH1C | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV50018649; called by muse, mutect2, varscan2
- USH2A | c.3116C>A p.A1039E | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1306207778, COSV56326600, COSV56357589; called by muse, mutect2, varscan2
- UVSSA | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 111/262 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs567453502; called by muse, mutect2, varscan2
- VAV1 | c.2336del p.G779Efs*82 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as COSV58379171; called by mutect2, pindel, varscan2
- VAX1 | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53327410; called by muse, mutect2, varscan2
- VIM | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV99812797; called by muse, mutect2, varscan2
- VNN1 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV63389652; called by muse, mutect2, varscan2
- VTI1B | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53619976; called by mutect2, varscan2
- VWF | c.7719C>A p.S2573R | Missense Mutation (SNP) | VAF 96/145 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs192262780; called by muse, mutect2, varscan2
- VWF | c.5348C>G p.S1783* | Nonsense Mutation (SNP) | VAF 68/263 reads (26%) | catalogued as COSV99779866; called by muse, mutect2, varscan2
- WAS | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV64997262; called by muse, mutect2, varscan2
- WIPF2 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100063227; called by mutect2, varscan2
- WNK3 | c.4210G>C p.E1404Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1557150435; called by muse, mutect2, varscan2
- WNT3 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843081; called by muse, varscan2
- WT1 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as CM065521, CM088240; called by muse, mutect2, varscan2
- XDH | c.648G>T p.L216F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751740411; called by muse, mutect2, varscan2
- XKR4 | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59339403; called by muse, mutect2, varscan2
- XPO7 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV53016579; called by mutect2, varscan2
- YTHDF1 | c.1000A>G p.R334G | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV64832800; called by muse, mutect2, varscan2
- ZC3H11A | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV59750707; called by muse, mutect2, varscan2
- ZC3H7B | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs889425116, COSV60960439; called by muse, mutect2, varscan2
- ZDBF2 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773248063; called by muse, mutect2, varscan2
- ZFHX4 | c.2065G>T p.G689C | Missense Mutation (SNP) | VAF 70/114 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51464208; called by muse, mutect2, varscan2
- ZFHX4 | c.10772C>G p.S3591C | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.927); catalogued as COSV51496862; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1855del p.H619Tfs*58 | Frame Shift Del (DEL) | VAF 79/316 reads (25%) | catalogued as COSV58744575; called by mutect2, pindel, varscan2
- ZMYND8 | c.9C>G p.I3M (on ENST00000311275 / NM_001363741.2; = p.I23M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV53687399; called by muse, mutect2, varscan2
- ZNF211 | c.481G>A p.A161T (on ENST00000347302 / NM_198855.4; = p.A174T on NM_006385.5) | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV53744763; called by muse, mutect2, varscan2
- ZNF33A | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 94/275 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100275657; called by muse, mutect2, varscan2
- ZNF385D | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as COSV55745121; called by muse, mutect2
- ZNF479 | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as COSV100482796; called by muse, mutect2, varscan2
- ZNF599 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV61396752; called by muse, mutect2, varscan2
- ZNF648 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); catalogued as rs772315055; called by muse, mutect2, varscan2
- ZNF697 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV70284321; called by muse, mutect2, varscan2
- ZNF804B | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60852751; called by muse, mutect2, varscan2
- ZNF804B | c.3769C>A p.P1257T | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100305144; called by muse, mutect2, varscan2
- ZNF831 | c.2995G>T p.G999C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs367871458; called by muse, mutect2, varscan2
- ABCA13 | c.5425C>G p.P1809A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA5 | c.1877G>T p.G626V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ABCA5 | c.1876G>C p.G626R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ABCB4 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ABCC12 | c.2995G>T p.G999C | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ABCC5 | c.2379+2T>A p.X793_splice | Splice Site (SNP) | VAF 50/98 reads (51%) | called by muse, mutect2, varscan2
- ABHD12B | c.704G>A p.C235Y (on ENST00000337334 / NM_001206673.2; = p.C158Y on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABLIM1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ABLIM1 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AC006059.2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ACAD10 | c.70A>C p.T24P | Missense Mutation (SNP) | VAF 71/113 reads (63%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAP2 | c.1315G>T p.G439* | Nonsense Mutation (SNP) | VAF 37/200 reads (19%) | called by muse, mutect2, varscan2
- ACP7 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACR | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACSS2 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN3 | c.1364A>G p.E455G | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACTRT1 | c.420T>A p.H140Q | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAM11 | c.336C>G p.Y112* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- ADAM20 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM21 | c.1904T>A p.L635H | Missense Mutation (SNP) | VAF 169/372 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAM23 | c.1940G>T p.W647L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.3972+1G>T p.X1324_splice | Splice Site (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3630G>A p.W1210* | Nonsense Mutation (SNP) | VAF 78/199 reads (39%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.4156del p.A1386Lfs*10 | Frame Shift Del (DEL) | VAF 72/229 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ADAMTS20 | c.3997G>T p.D1333Y | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS6 | c.2839del p.R947Gfs*94 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- ADAT1 | c.1319G>T p.R440I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ADCY1 | c.1169A>G p.E390G | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- ADCY1 | c.3060G>T p.V1020= | Splice Region (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- ADCY8 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, varscan2
- ADGRG2 | c.397G>T p.E133* (on ENST00000379869 / NM_001079858.3; = p.E130* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- ADGRG4 | c.2347G>C p.V783L | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ADGRG4 | c.4697C>A p.P1566Q | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ADGRG6 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ADGRL2 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ADIPOR1 | c.259-1G>T p.X87_splice | Splice Site (SNP) | VAF 66/340 reads (19%) | called by muse, mutect2, varscan2
- ADRA2B | c.1148G>T p.C383F | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGAP4 | c.1159A>T p.N387Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AGBL1 | c.541A>T p.R181* | Nonsense Mutation (SNP) | VAF 46/162 reads (28%) | called by muse, mutect2, varscan2
- AGPAT5 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHI1 | c.2208G>T p.L736F | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- AK5 | c.380C>A p.P127H (on ENST00000354567 / NM_174858.3; = p.P101H on NM_012093.4) | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- AK5 | c.1387T>A p.Y463N (on ENST00000354567 / NM_174858.3; = p.Y437N on NM_012093.4) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP12 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AKAP13 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- AKAP5 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALAD | c.827A>T p.Y276F | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ALDH18A1 | c.1107G>T p.M369I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ALDH1L1 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALMS1 | c.8379del p.R2793Sfs*20 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- ALPI | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 165/472 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- AMELX | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMER3 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AMIGO1 | c.1364del p.G455Afs*124 | Frame Shift Del (DEL) | VAF 33/151 reads (22%) | called by mutect2, pindel, varscan2
- AMMECR1 | c.525C>G p.C175W | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 104/170 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ANK2 | c.9299C>G p.P3100R | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD12 | c.5623C>G p.L1875V | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD30A | c.3428A>G p.N1143S (on ENST00000611781; = p.N1087S on NM_052997.2) | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ANKRD50 | c.1763A>C p.Q588P | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ANKZF1 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO2 | c.492G>T p.E164D (on ENST00000356134 / NM_001278597.3; = p.E168D on NM_001278596.3) | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, varscan2
- ANO6 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANO9 | c.2241G>A p.M747I | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APBA2 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ARC | c.801C>G p.F267L | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ARFGAP1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ARHGAP10 | c.1868-1G>T p.X623_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ARHGAP6 | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- ARID4A | c.3173G>C p.C1058S | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARL11 | c.487C>G p.P163A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARL13A | c.710C>A p.S237* | Nonsense Mutation (SNP) | VAF 120/444 reads (27%) | called by muse, varscan2
- ARNT2 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARSA | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSK | c.127-1G>T p.X43_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- ASB17 | c.124T>G p.C42G | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ASPRV1 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ASTN1 | c.2825C>A p.S942Y | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATAD2B | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ATG2B | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ATM | c.9080G>T p.S3027I | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATOH1 | c.98del p.P33Rfs*74 | Frame Shift Del (DEL) | VAF 92/342 reads (27%) | called by mutect2, varscan2
- ATP6V0D2 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN1 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AURKC | c.661del p.D221Ifs*34 (on ENST00000302804 / NM_001015878.2; = p.D187Ifs*34 on NM_003160.3) | Frame Shift Del (DEL) | VAF 56/144 reads (39%) | called by mutect2, pindel, varscan2
- B4GALT5 | c.757A>T p.R253W | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAIAP2L1 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCO2 | c.1583A>C p.E528A | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCORL1 | c.486G>T p.L162F | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.901); called by muse, varscan2
- BCORL1 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); called by muse, varscan2
- BCORL1 | c.3454C>A p.P1152T | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- BCORL1 | c.4518G>T p.W1506C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BEX1 | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- BEX5 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- BMPER | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- BMPER | c.1669C>A p.H557N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- BMPR1A | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- BOC | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, varscan2
- BOD1L1 | c.1204G>T p.G402* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- BPHL | c.718C>A p.H240N | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPIFB6 | c.1341G>T p.M447I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BPIFC | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 139/190 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, varscan2
- BPNT1 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- BRINP3 | c.1899_1900delinsT p.K634Sfs*28 | Frame Shift Del (DEL) | VAF 69/202 reads (34%) | called by pindel, varscan2*
- BRWD3 | c.2287G>T p.V763F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BST1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- BTBD8 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- BTG2 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN3A3 | c.1019-2A>T p.X340_splice | Splice Site (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- C10orf71 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- C10orf82 | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, varscan2
- C10orf90 | c.1863C>A p.S621R | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- C10orf90 | c.1379G>C p.C460S | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- C14orf39 | c.893C>A p.A298E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C16orf82 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C16orf92 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- C22orf42 | c.466-1G>C p.X156_splice | Splice Site (SNP) | VAF 166/242 reads (69%) | called by mutect2, varscan2
- CACNA1A | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CACNA1E | c.3152C>A p.P1051H | Missense Mutation (SNP) | VAF 233/897 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- CACNA1E | c.6788C>A p.S2263Y (on ENST00000367573 / NM_001205293.3; = p.S2220Y on NM_000721.4) | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CACNA1S | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 314/582 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D4 | c.1129C>A p.L377M | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CACNB4 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CAMTA1 | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 110/213 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAND1 | c.90G>C p.L30F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPN6 | c.1609G>T p.V537L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- CARD11 | c.1233G>T p.E411D | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CARD6 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CCDC170 | c.1688T>A p.L563Q | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC180 | c.3423G>T p.Q1141H | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CCDC39 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CCDC39 | c.1167G>A p.K389= | Splice Region (SNP) | VAF 15/36 reads (42%) | called by mutect2, varscan2
- CCDC69 | c.589A>T p.R197W | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- CCDC73 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC86 | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- CCIN | c.1330G>T p.V444L | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CCN6 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCNB3 | c.2915del p.G972Efs*14 | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | called by mutect2, pindel, varscan2
- CCNL2 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 112/222 reads (50%) | called by muse, mutect2, varscan2
- CCT6A | c.1176G>T p.R392S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CD5L | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CD99 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 194/360 reads (54%) | called by muse, varscan2
- CDC14A | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CDC42BPA | c.2614G>C p.A872P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CDH12 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CDH18 | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CDH19 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDH2 | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CDH2 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CDH23 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- CDH7 | c.216C>G p.H72Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- CDH7 | c.1150A>T p.M384L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.265); called by muse, mutect2
- CDK8 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CDKAL1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- CELSR1 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CEMIP | c.2389C>A p.R797S | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEMIP2 | c.1243G>T p.G415* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2
- CENPE | c.4819G>T p.D1607Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CENPE | c.2480T>A p.M827K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPE | c.1045A>T p.R349* | Nonsense Mutation (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- CEP170 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CEP170 | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP250 | c.4354G>T p.E1452* | Nonsense Mutation (SNP) | VAF 73/144 reads (51%) | called by muse, mutect2, varscan2
- CES5A | c.1583G>T p.G528V (on ENST00000290567 / NM_001143685.2; = p.G478V on NM_145024.3) | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP46 | c.6817G>A p.E2273K | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CFAP46 | c.5798G>A p.G1933E | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP46 | c.5719G>T p.A1907S | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CFAP47 | c.1143T>G p.F381L | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CFHR2 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.629); called by muse, mutect2
- CFHR3 | c.334G>C p.V112L | Missense Mutation (SNP) | VAF 281/574 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CFHR5 | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 128/260 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CHD7 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CHGB | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CHGB | c.1525C>A p.H509N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CHRNA9 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CHST3 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CIITA | c.1341T>G p.F447L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- CLSTN2 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLSTN2 | c.1559C>A p.A520D | Missense Mutation (SNP) | VAF 156/271 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CMYA5 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- CNGA2 | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CNGA2 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 89/297 reads (30%) | called by muse, mutect2, varscan2
1,455 further variants in this file (907 protein-altering or splice-affecting, 494 silent, 54 other) are not listed here.
